Somatic mutation profile of tumor specimen C3L-06538-54 (aliquot CPT0357740002) from CPTAC case C3L-06538, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 65.2 years (23,821 days).
Specimen C3L-06538-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54968ba5-4e18-4625-aa71-e0181df9c141.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06538-51 (Buccal Cell Normal), aliquot CPT0357710003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c27d8fb-5b81-4999-9fd8-7d790d7034a9

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NR2C2 | c.1777G>A p.G593R (on ENST00000393102; = p.G612R on NM_003298.5) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1559315010, COSV60144600; called by muse, mutect2, varscan2
- FLT3 | c.2822_2823insACTCATCTC p.S941_F942insLIS | In Frame Ins (INS) | VAF 36/199 reads (18%) | called by mutect2, pindel, varscan2
- PROC | c.477_480dup p.S161Lfs*2 | Frame Shift Ins (INS) | VAF 89/237 reads (38%) | called by mutect2, varscan2
- SNED1 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
